Somatic mutation profile of tumor specimen MP2PRT-PARUDF-TMP1-A (aliquot MP2PRT-PARUDF-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARUDF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (804 days).
Specimen MP2PRT-PARUDF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcff051b-cce5-46e4-9e3a-22fe4e64d0e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUDF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUDF-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc6c5a42-81d4-41bf-8141-ff43b1abbad4

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'Flank 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP16 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 98/140 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs753103309; called by muse, mutect2, varscan2
- KLHL41 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 102/290 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs368251922, COSV52929481; called by muse, mutect2, varscan2
- LRBA | c.6430C>T p.R2144C | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933140899, COSV63952766; called by muse, mutect2, varscan2
- SHISA2 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752233986; called by muse, mutect2, varscan2
- ROBO2 | c.4115G>A p.G1372E | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBA2 | c.719_721del p.T240del | In Frame Del (DEL) | VAF 54/194 reads (28%) | called by pindel, varscan2
- BIN1 | c.915C>T p.A305= (on ENST00000316724 / NM_001320642.1; = p.A289= on NM_004305.4) | Silent (SNP) | VAF 55/599 reads (9%) | catalogued as rs761585447; ClinVar: likely benign; called by muse, mutect2
- CBX2 | c.288+113A>T | Intron (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- IGHV1-58 | chr14:106627248 ins CCTCCCTACA | 5'Flank (INS) | VAF 6/31 reads (19%) | called by pindel, varscan2
